Somatic mutation profile of tumor specimen MBCProject_0096_T1_WES (aliquot MBCProject_0096_T1_WES_1) from CMI case MBCProject_0096, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 32.0 years (11,706 days).
Specimen MBCProject_0096_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 651c494b-7304-44bf-b0ab-25a0c56c8e3f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0096_SALIVA (Saliva), aliquot MBCProject_0096_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8113ae52-c35e-463b-9d94-cbb6f9618ee3

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, In Frame Del 2, Intron 2, RNA 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1349_1363del p.H450_D454del | In Frame Del (DEL) | VAF 3/37 reads (8%) | catalogued as COSV55900724; called by mutect2, pindel
- SPP1 | c.646G>A p.D216N (on ENST00000395080 / NM_001040058.2; = p.D202N on NM_000582.2) | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.82); catalogued as rs1418078561; called by muse, mutect2, varscan2
- AKT2 | c.259A>G p.T87A | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- ANGPTL6 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); called by muse, varscan2
- CLOCK | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GOLPH3L | c.269A>C p.Y90S | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IPO7 | c.1198G>T p.A400S | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- KIAA1549L | c.1021G>C p.V341L (on ENST00000321505; = p.V638L on NM_012194.3) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKM | c.1061A>G p.D354G | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- PTEN | c.99_104del p.I33_A34del | In Frame Del (DEL) | VAF 12/78 reads (15%) | called by mutect2, pindel, varscan2
- SLC2A7 | c.49G>C p.G17R | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.722); called by mutect2, varscan2
- SIRT6 | c.441G>A p.Q147= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as COSV50256646; called by muse, mutect2
- CBFA2T2 | c.719+627T>C | Intron (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- SSPOP | n.9275G>A | RNA (SNP) | VAF 5/36 reads (14%) | catalogued as rs150092603, COSV100948203, COSV65126999; called by muse, mutect2, varscan2
- UBL4A | c.155-60C>T | Intron (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
